Gene-level copy-number profile of tumor specimen TCGA-DU-7302-01A from TCGA case TCGA-DU-7302, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.3 years (17,656 days).
Specimen TCGA-DU-7302-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.44c39269-efcd-4f13-afd6-a7cf8d959e0e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-7302-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a512211b-aa73-40e7-854d-3f640a233619

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,353; copy number 2: 51,022; copy number 4: 59; copy number 6: 386.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-7302-01A-11D-2085-01): tumor purity 0.88, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 386 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,049,073–56,328,625, 1 gene, copy number 6 (within-gene range 4–6): CRACD.
- chr4:56,288,485–62,510,771, 74 genes, copy number 6 (broad region; genes not listed).
- chr14:21,070,273–25,156,314, 311 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,353. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
